Somatic mutation profile of tumor specimen 1105204 (aliquot 7316UP-1302-1105204) from CPTAC case C524103, project CPTAC-3 (Other and unspecified urinary organs — Nevi and Melanomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Urethra.
Specimen 1105204: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Cerebrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 261decfc-0573-4eae-bee5-2e5188515f05.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105274 (Blood Derived Normal), aliquot 7316UP-1302-1105274; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4ab693e1-5fc2-4f1c-bd70-f088e2119053

The open-access MAF lists 46 somatic variants for this specimen: 30 protein-altering or splice-affecting, 14 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 14, Intron 2, Nonsense Mutation 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.721T>A p.S241T | Missense Mutation (SNP) | VAF 50/284 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CD984149, CM942121, COSV52670786, COSV52675302, COSV53004514; called by muse, mutect2, varscan2
- ALOX5 | c.805C>T p.R269W | Missense Mutation (SNP) | VAF 32/151 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs778418203; called by muse, mutect2, varscan2
- DSCAM | c.1045C>T p.R349C | Missense Mutation (SNP) | VAF 44/320 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1227425619, COSV68021037; called by muse, mutect2, varscan2
- FRAS1 | c.811C>A p.H271N | Missense Mutation (SNP) | VAF 50/325 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.158); catalogued as COSV53598598; called by muse, mutect2, varscan2
- GPT2 | c.1165G>A p.V389M | Missense Mutation (SNP) | VAF 27/164 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs143451663; called by muse, mutect2, varscan2
- GRIN2B | c.3169C>T p.R1057C | Missense Mutation (SNP) | VAF 88/454 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs761084398; called by muse, mutect2, varscan2
- LLGL1 | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 19/174 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as rs775418941, COSV57496026; called by muse, mutect2, varscan2
- MGAT5 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs768197190, COSV56094792; called by muse, mutect2, varscan2
- NEK10 | c.1718C>G p.S573C | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs1264897408; called by mutect2, varscan2
- OR6Y1 | c.775A>G p.M259V | Missense Mutation (SNP) | VAF 22/187 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs909829305; called by muse, mutect2, varscan2
- RASA2 | c.2275_2276del p.E759Kfs*12 | Frame Shift Del (DEL) | VAF 7/65 reads (11%) | catalogued as rs756946687; called by mutect2, pindel, varscan2
- REG3G | c.262G>A p.V88M | Missense Mutation (SNP) | VAF 24/235 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); catalogued as rs779615598, COSV55449323, COSV55450779; called by muse, mutect2, varscan2
- ROBO3 | c.1001G>A p.R334H | Missense Mutation (SNP) | VAF 24/244 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs373820994; called by muse, mutect2
- SYT4 | c.127T>C p.S43P | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as COSV54904546; called by muse, mutect2, varscan2
- ZNF718 | c.678C>G p.F226L | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV101210245; called by muse, varscan2
- ATRX | c.3271A>T p.K1091* | Nonsense Mutation (SNP) | VAF 26/235 reads (11%) | called by muse, mutect2, varscan2
- CACNA1I | c.1105G>A p.A369T | Missense Mutation (SNP) | VAF 21/187 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL4A1 | c.4865G>A p.C1622Y | Missense Mutation (SNP) | VAF 44/464 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- IGKV5-2 | c.19C>T p.L7F | Missense Mutation (SNP) | VAF 26/372 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2
- NEB | c.11696T>G p.I3899S | Missense Mutation (SNP) | VAF 20/169 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- ORC1 | c.1901A>G p.Y634C | Missense Mutation (SNP) | VAF 104/555 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PGAP2 | c.483C>G p.C161W (on ENST00000463452 / NM_001346398.2; = p.C222W on NM_014489.4) | Missense Mutation (SNP) | VAF 23/216 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RALGAPA1 | c.1660C>T p.H554Y | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- SCUBE1 | c.703C>A p.H235N | Missense Mutation (SNP) | VAF 25/241 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- SLC23A3 | c.742A>T p.R248W (on ENST00000409878 / NM_001144889.2; = p.G237= on NM_144712.5) | Missense Mutation (SNP) | VAF 8/135 reads (6%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.936); called by muse, mutect2
- TEPSIN | c.832T>A p.C278S | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRIOBP | c.5250G>A p.W1750* | Nonsense Mutation (SNP) | VAF 57/530 reads (11%) | called by muse, mutect2, varscan2
- TRPC7 | c.1555C>A p.P519T | Missense Mutation (SNP) | VAF 23/171 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- ZNF718 | c.635C>T p.S212L | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, varscan2
- ZNF91 | c.2231G>A p.C744Y | Missense Mutation (SNP) | VAF 26/187 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- AKAP3 | c.2557C>T p.L853= | Silent (SNP) | VAF 20/135 reads (15%) | catalogued as rs780846438; called by muse, mutect2
- AQR | c.852C>T p.Y284= | Silent (SNP) | VAF 23/158 reads (15%) | called by muse, mutect2, varscan2
- CEP250 | c.5244C>T p.L1748= | Silent (SNP) | VAF 26/226 reads (12%) | catalogued as rs1296536087; called by muse, mutect2, varscan2
- DACT2 | c.1542G>A p.P514= | Silent (SNP) | VAF 31/197 reads (16%) | catalogued as rs890309903; called by muse, mutect2, varscan2
- EFCAB14 | c.108T>G p.P36= | Silent (SNP) | VAF 53/277 reads (19%) | called by muse, mutect2, varscan2
- FAM170B | c.768G>A p.E256= | Silent (SNP) | VAF 36/183 reads (20%) | catalogued as rs1358578431; called by muse, mutect2, varscan2
- GCN1 | c.7848T>A p.I2616= | Silent (SNP) | VAF 40/250 reads (16%) | called by muse, varscan2
- MAP4K2 | c.1764G>C p.L588= | Silent (SNP) | VAF 20/160 reads (13%) | called by muse, varscan2
- MYO15A | c.2352G>A p.P784= | Silent (SNP) | VAF 20/175 reads (11%) | catalogued as rs748006735; called by muse, mutect2, varscan2
- NBEAL2 | c.888C>G p.P296= | Silent (SNP) | VAF 36/198 reads (18%) | catalogued as rs375562306; called by muse, mutect2, varscan2
- PDCD7 | c.480G>A p.P160= | Silent (SNP) | VAF 17/108 reads (16%) | called by muse, mutect2, varscan2
- XKR4 | c.1488C>T p.F496= | Silent (SNP) | VAF 30/402 reads (7%) | called by muse, mutect2
- XKR4 | c.1782C>T p.V594= | Silent (SNP) | VAF 33/265 reads (12%) | called by muse, mutect2, varscan2
- ZBTB10 | c.1269C>T p.F423= | Silent (SNP) | VAF 32/322 reads (10%) | called by muse, mutect2
- CABIN1 | c.4117+57dup | Intron (INS) | VAF 44/311 reads (14%) | catalogued as rs766082760; called by mutect2, varscan2
- SMARCC1 | c.1899+20T>C | Intron (SNP) | VAF 12/115 reads (10%) | catalogued as rs1029053019; called by muse, mutect2, varscan2
